Somatic mutation profile of tumor specimen TCGA-TM-A84R-01A (aliquot TCGA-TM-A84R-01A-21D-A36O-08) from TCGA case TCGA-TM-A84R, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 46.1 years (16,843 days).
Specimen TCGA-TM-A84R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d1b1813-689d-4ceb-b58a-758ba0db5934.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84R-10A (Blood Derived Normal), aliquot TCGA-TM-A84R-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d252e3d6-8486-40b4-8290-7b5ab5eedf36

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRD2 | c.1199A>G p.K400R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as rs986806490, COSV100875587, COSV66374745; called by muse, mutect2
- GNA14 | c.651G>T p.E217D | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV100502634; called by muse, mutect2
- OR4L1 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367946088; called by muse, varscan2
- RTN4RL2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs956374071, COSV100625407; called by muse, mutect2
- GLUD2 | c.1434T>C p.F478= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV100046655; called by muse, mutect2, varscan2
- TUBGCP5 | c.1881G>A p.K627= | Silent (SNP) | VAF 7/193 reads (4%) | called by muse, mutect2
